Gene-level copy-number profile of tumor specimen TCGA-06-6693-01A from TCGA case TCGA-06-6693, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.6 years (23,585 days).
Specimen TCGA-06-6693-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.120f4228-974c-469b-b3a3-4ee552ad55c1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-6693-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dec895d5-a86c-4304-b9cd-c68f3b4c1390

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 9,930; copy number 2: 49,808; copy number 3: 24; copy number 4: 24; copy number 15: 8; copy number 17: 1; copy number 18: 9; copy number 32: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-6693-01A-11D-1842-01): tumor purity 0.88, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 22 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,759,348–55,211,628, 4 genes, copy number 32 (within-gene range 1–32): SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.
- chr8:126,556,323–127,419,050, 1 gene, copy number 15 (within-gene range 1–15): PCAT1.
- chr8:127,072,694–127,482,139, 7 genes, copy number 15 (within-gene range 1–18): CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B.
- chr8:127,578,473–128,187,101, 9 genes, copy number 18 (within-gene range 1–18): AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205.
- chr8:128,220,504–128,220,803, 1 gene, copy number 17: RN7SKP226.

Autosomal genes at a single copy (total copy number 1): 9,927. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
